Gene-level copy-number profile of tumor specimen TCGA-06-0221-02A from TCGA case TCGA-06-0221, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 31.0 years (11,333 days).
Specimen TCGA-06-0221-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.51bd8ec3-b7a6-4375-a7b0-24d40eb7b141.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0221-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/226db61d-ff0f-4849-afb8-b6d7070567e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 7,564; copy number 2: 50,819; copy number 3: 1,510; copy number 4: 136; copy number 5: 1; copy number 6: 18; copy number 7: 26; copy number 8: 63; copy number 10: 2; copy number 11: 33; copy number 12: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0221-02A-11D-2002-01): tumor purity 0.82, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–26,118,408, 89 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 152 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–1,744,852, 37 genes, copy number 5–11 (within-gene range 3–11): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN.
- chr2:2,697,490–3,126,026, 5 genes, copy number 7–11 (within-gene range 3–11): AC018685.3, AC011995.2, AC018685.1, AC011995.1, LINC01250.
- chr2:3,188,925–3,377,830, 2 genes, copy number 7 (within-gene range 3–7): EIPR1, EIPR1-IT1.
- chr2:3,481,242–3,497,428, 2 genes, copy number 10: TRAPPC12-AS1, AC114810.1.
- chr2:3,658,200–3,848,008, 4 genes, copy number 8 (within-gene range 3–8): ALLC, GAPDHP48, AC010907.1, DCDC2C.
- chr2:4,514,204–4,945,383, 4 genes, copy number 8: NPM1P48, LINC01249, AC092169.1, RNU6-649P.
- chr2:5,932,543–6,375,422, 4 genes, copy number 8: SILC1, MIR7158, AC017053.1, LINC01247.
- chr2:6,917,412–7,325,062, 5 genes, copy number 8 (within-gene range 3–8): RNF144A, AC068481.1, RN7SKP112, AC010904.2, AC010904.1.
- chr2:7,671,330–7,675,736, 2 genes, copy number 8: AC092580.4, AC092580.2.
- chr2:8,461,703–8,622,942, 4 genes, copy number 7: LINC01814, AC092617.1, AC011747.1, SNRPEP5.
- chr2:9,081,395–9,146,106, 5 genes, copy number 6–8: RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1.
- chr2:15,166,914–16,333,978, 24 genes, copy number 7–12 (within-gene range 3–12): NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4.
- chr2:17,284,292–18,361,616, 9 genes, copy number 8 (within-gene range 3–8): ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1.
- chr2:18,784,807–18,946,650, 2 genes, copy number 7: AC106053.1, AC130814.1.
- chr2:20,246,326–21,198,896, 23 genes, copy number 8: RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3, LDAH, LINC02850, AC115619.1, APOB, AC010872.1, AC010872.2, TDRD15, AC067959.1.
- chr2:21,317,660–21,561,313, 2 genes, copy number 8: AC011752.1, NUTF2P8.
- chr2:22,861,552–23,199,056, 2 genes, copy number 11: RN7SKP27, AC018467.1.
- chr12:4,247,981–4,405,490, 6 genes, copy number 6–7 (within-gene range 1–7): CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23.
- chr12:4,538,798–4,774,184, 10 genes, copy number 6 (within-gene range 1–6): RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1.

Autosomal genes at a single copy (total copy number 1): 5,169. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
